FM case AD13293 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Anus and anal canal.
https://portal.gdc.cancer.gov/cases/517f48e3-ad58-4b0d-a710-84588d29d1da

Male, 69.5 years: Melanoma, NOS (ICD-O-3 8720/3) of the anus; metastasis biopsied or resected from the colon. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
